Somatic mutation profile of tumor specimen TCGA-DX-A6YT-01A (aliquot TCGA-DX-A6YT-01A-21D-A351-09) from TCGA case TCGA-DX-A6YT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 31.8 years (11,633 days).
Specimen TCGA-DX-A6YT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 216d17f3-cadb-4f67-b126-56b13295ec31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YT-10B (Blood Derived Normal), aliquot TCGA-DX-A6YT-10B-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7586fc1-7ed4-4f5f-b9dd-69567b92aa92

The open-access MAF lists 90 somatic variants for this specimen: 74 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 15, Nonsense Mutation 3, Translation Start Site 1, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as rs1414143303, CM042962, COSV51811925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.1295G>T p.S432I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV51973710; called by muse, mutect2, varscan2
- ADAM19 | c.2224C>A p.L742M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.453); catalogued as COSV99977869; called by mutect2, varscan2
- ADPGK | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV100295304; called by mutect2, varscan2
- ALDH9A1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100699316; called by muse, mutect2, varscan2
- AQR | c.2177C>A p.A726D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99334333; called by muse, mutect2
- ATP6AP2 | c.886T>C p.Y296H (on ENST00000378438; = p.Y297H on NM_005765.3) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV101011547; called by muse, mutect2, varscan2
- ATP8A1 | c.597C>A p.G199= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100046775; called by mutect2, varscan2
- B3GALT4 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV101005671; called by muse, varscan2
- C12orf71 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as rs1555115279, COSV101460540; called by mutect2, varscan2
- CC2D1B | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99430134; called by mutect2, varscan2
- CCDC171 | c.2004G>T p.E668D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV99901400; called by mutect2, varscan2
- CEP164 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV99633908; called by muse, mutect2, varscan2
- CETN3 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99300611; called by muse, mutect2
- CHRM4 | c.1284C>A p.S428R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.532); catalogued as COSV100551736; called by mutect2, varscan2
- CLEC10A | c.573C>A p.S191R (on ENST00000254868 / NM_182906.4; = p.S167R on NM_006344.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99644786; called by muse, mutect2, varscan2
- CLRN1 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV58997307; called by mutect2, varscan2
- CNTLN | c.3753G>T p.Q1251H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV52092074, COSV99265002; called by muse, mutect2
- CRNKL1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99845844; called by mutect2, varscan2
- CYP2C9 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53250167, COSV99582961; called by muse, mutect2
- CYP3A7 | c.1112T>A p.M371K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV100312760; called by muse, mutect2, varscan2
- DDC | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100779631; called by mutect2, varscan2
- DHX30 | c.1535G>T p.R512L (on ENST00000445061 / NM_138615.3; = p.R473L on NM_014966.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as COSV53136632, COSV99275843; called by muse, mutect2
- DISP3 | c.2739G>T p.K913N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as COSV99607551, COSV99609397; called by muse, mutect2, varscan2
- DRP2 | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871983; called by mutect2, varscan2
- ECE1 | c.303C>A p.S101R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV51664284, COSV99942118; called by mutect2, varscan2
- EFEMP2 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.243); catalogued as COSV100337312; called by mutect2, varscan2
- EFR3A | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99603310; called by muse, mutect2, varscan2
- ERLIN1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100962294; called by muse, varscan2
- FASTKD3 | c.1748C>A p.A583D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs773495015, COSV99242630; called by mutect2, varscan2
- FOCAD | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV100620580, COSV58107863; called by muse, mutect2, varscan2
- GBP5 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600138; called by muse, mutect2
- GOLM1 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99974449; called by muse, mutect2, varscan2
- GPR84 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99910102; called by muse, mutect2, varscan2
- HEATR5A | c.3566G>C p.C1189S | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101120290; called by muse, mutect2, varscan2
- HEATR9 | c.880A>G p.M294V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751512814; called by muse, mutect2, varscan2
- HHIP | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99667571; called by mutect2, varscan2
- HIRA | c.2152C>A p.L718M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99600682; called by mutect2, varscan2
- HYOU1 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101345634; called by muse, varscan2
- IGKV1D-8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 57/85 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); catalogued as rs538313788; called by muse, mutect2, varscan2
- INPP5F | c.1887-1G>T p.X629_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100740281; called by muse, mutect2, varscan2
- ITPR3 | c.6169G>T p.A2057S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100967736; called by mutect2, varscan2
- IVL | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.925); catalogued as rs745528868, COSV100908214; called by muse, mutect2, varscan2
- LAMC2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV99917690; called by mutect2, varscan2
- LDHC | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV99772609; called by muse, mutect2, varscan2
- LRRK2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV100110827; called by mutect2, varscan2
- LSS | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100710980; called by muse, mutect2, varscan2
- MFSD4A | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100901650; called by mutect2, varscan2
- MLC1 | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100286468; called by muse, mutect2, varscan2
- NEURL4 | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as COSV100223146; called by muse, mutect2, varscan2
- NFKBIZ | c.1861G>T p.A621S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100397145; called by mutect2, varscan2
- OR2L13 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100813724; called by muse, varscan2
- PCM1 | c.4391G>T p.S1464I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256924873, COSV100279303; called by muse, mutect2, varscan2
- PEX13 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV99692961; called by mutect2, varscan2
- PIAS1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs865886441; called by muse, mutect2
- POLR2G | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080152, COSV57135000; called by muse, mutect2
- PRAG1 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100422515; called by mutect2, varscan2
- PRRC2B | c.6584G>T p.S2195I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV100261080; called by mutect2, varscan2
- RAD54L2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99621615; called by mutect2, varscan2
- RBBP4 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100995737; called by muse, mutect2, varscan2
- RGS6 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as rs1332457033, COSV59569531; called by muse, mutect2, varscan2
- RYR1 | c.8476G>T p.A2826S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV100616412; called by mutect2, varscan2
- SEPTIN4 | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100400403, COSV58727396; called by muse, mutect2, varscan2
- SLC9A6 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV100857926; called by mutect2, varscan2
- SPTA1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs374406059; called by muse, mutect2, varscan2
- TACC3 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as COSV100508856; called by mutect2, varscan2
- TMCC1 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV101282058; called by mutect2, varscan2
- TTC33 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV100531986; called by mutect2, varscan2
- TTN | c.98272G>A p.D32758N (on ENST00000591111; = p.D25334N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | PolyPhen probably damaging (0.998); catalogued as COSV100621744; called by muse, mutect2, varscan2
- WDR35 | c.2234C>A p.A745D (on ENST00000345530 / NM_001006657.2; = p.A734D on NM_020779.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99853346; called by muse, mutect2, varscan2
- ZNF133 | c.1235G>T p.C412F (on ENST00000316358 / NM_001352454.2; = p.C411F on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100315591; called by muse, mutect2
- AREL1 | c.2380C>A p.L794M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RBM39 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- TRBV5-1 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- AL669918.1 | c.2437C>T p.L813= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV101441058; called by muse, mutect2, varscan2
- ARL4D | c.201G>T p.S67= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- EIF2D | c.1092C>T p.S364= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99662931; called by muse, mutect2, varscan2
- INO80 | c.3000C>A p.R1000= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100731969; called by muse, mutect2, varscan2
- KCNJ10 | c.612C>T p.R204= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100927938; called by muse, varscan2
- MAPK10 | c.379C>A p.R127= (on ENST00000359221 / NM_001351625.2; = p.R165= on NM_002753.5) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100174982, COSV60385697; called by muse, mutect2
- MRI1 | c.732C>T p.V244= (on ENST00000040663 / NM_001031727.4; = p.V197= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs369354524; called by muse, mutect2
- MRPL15 | c.558T>C p.I186= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV99477593; called by muse, mutect2, varscan2
- MYL2 | c.495G>A p.K165= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99960824; called by muse, mutect2, varscan2
- NEURL4 | c.3540C>T p.F1180= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59753115; called by muse, mutect2, varscan2
- NPC1 | c.3585C>A p.G1195= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99340299; called by muse, mutect2
- SCN4A | c.2082C>A p.G694= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101438575; called by mutect2, varscan2
- TRPM4 | c.2202G>T p.G734= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99420498; called by mutect2, varscan2
- UNC93B1 | c.633C>A p.G211= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99916465, COSV99916551; called by mutect2, varscan2
- WDR62 | c.3708C>T p.I1236= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs775723707, COSV99543955; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622912 G>T | 3'Flank (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100247245; called by mutect2, varscan2
